Somatic mutation profile of tumor specimen TCGA-MX-A5UJ-01A (aliquot TCGA-MX-A5UJ-01A-11D-A31L-08) from TCGA case TCGA-MX-A5UJ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 86.3 years (31,517 days).
Specimen TCGA-MX-A5UJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 848e15be-398f-49f1-a4f4-ae1b8876e195.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MX-A5UJ-10A (Blood Derived Normal), aliquot TCGA-MX-A5UJ-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd17c199-224e-4d3e-b16a-d04873c8b645

The open-access MAF lists 1,706 somatic variants for this specimen: 1,301 protein-altering or splice-affecting, 370 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 832, Silent 370, Frame Shift Del 303, Frame Shift Ins 72, Nonsense Mutation 44, Splice Site 19, Splice Region 16, Intron 15, In Frame Del 15, 3'UTR 9, RNA 4, 5'UTR 3.

Variants (750 of 1,706; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5196+1G>A p.X1732_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | catalogued as rs61751377, CS124701, CS971603, COSV100933078; ClinVar: pathogenic; called by muse, varscan2
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 30/142 reads (21%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 35/196 reads (18%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BBS9 | c.263+1G>A p.X88_splice | Splice Site (SNP) | VAF 16/74 reads (22%) | catalogued as rs137962929, CS1414372; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BSCL2 | c.782dup p.I262Hfs*12 | Frame Shift Ins (INS) | VAF 16/82 reads (20%) | catalogued as rs749890533; ClinVar: pathogenic; called by mutect2, varscan2
- ERBB2 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 71/349 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 30/215 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- FLG | c.9887C>A p.S3296* | Nonsense Mutation (SNP) | VAF 156/814 reads (19%) | catalogued as rs761212672, CM081617, COSV64243990; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GBA | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1141814, CM950561, COSV100516282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by pindel, varscan2
- HPSE2 | c.57dup p.A20Rfs*45 | Frame Shift Ins (INS) | VAF 18/104 reads (17%) | catalogued as rs778121647; ClinVar: pathogenic; called by mutect2, varscan2
- MC2R | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs104894660, CM002358, COSV59617811; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587783841, CM960998, COSV60334236; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEDD4L | c.2690G>A p.R897Q (on ENST00000400345 / NM_001144967.3; = p.R877Q on NM_015277.6) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs879255596; ClinVar: pathogenic; called by muse, mutect2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PROK2 | c.297del p.F99Lfs*28 (on ENST00000295619 / NM_001126128.2; = p.F78Lfs*28 on NM_021935.4) | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | catalogued as rs768413190; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- SERPINA1 | c.1158del p.E387Rfs*11 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | catalogued as rs764325655, CD890162; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SYNGAP1 | c.1001del p.K334Sfs*13 | Frame Shift Del (DEL) | VAF 33/153 reads (22%) | catalogued as rs1561784687; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TK2 | c.220C>T p.R74W (on ENST00000299697; = p.R130W on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs281865493, CM074600, COSV55281306; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.57583C>T p.R19195* (on ENST00000591111; = p.R11771* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 27/142 reads (19%) | catalogued as rs757231565, CM1514640, COSV100587641; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2M | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV100588562; called by muse, mutect2
- ABCA2 | c.4414G>A p.G1472R (on ENST00000614293; = p.G1442R on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99687278; called by muse, mutect2, varscan2
- ABCA2 | c.2534C>T p.S845L (on ENST00000614293; = p.S815L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1233870167, COSV55802453; called by muse, mutect2, varscan2
- ABCA3 | c.4214C>T p.A1405V | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs149559041; called by muse, mutect2, varscan2
- ABCB1 | c.1480A>G p.N494D | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55945523, COSV99712535; called by muse, mutect2, varscan2
- ABCB10 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs780229410, COSV60621008; called by muse, mutect2, varscan2
- ABCB11 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs200509511; called by muse, mutect2, varscan2
- ABCB8 | c.414G>A p.W138* (on ENST00000297504 / NM_001282291.2; = p.W121* on NM_007188.5) | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99874104; called by muse, mutect2, varscan2
- ABCC10 | c.3314G>A p.S1105N (on ENST00000372530 / NM_001198934.2; = p.S1077N on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs563859978, COSV55093521; called by muse, mutect2, varscan2
- ABCC6 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs200330935, COSV52749431; called by muse, mutect2, varscan2
- ABCC9 | c.3252del p.F1084Lfs*8 | Frame Shift Del (DEL) | VAF 21/147 reads (14%) | catalogued as rs1443617329, COSV53986962; called by mutect2, pindel, varscan2
- ABTB2 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as rs367642739; called by muse, mutect2, varscan2
- ACIN1 | c.3934C>T p.R1312* | Nonsense Mutation (SNP) | VAF 50/184 reads (27%) | catalogued as rs756480020, COSV52976153; called by muse, varscan2
- ACP7 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.911); catalogued as rs759947307, COSV100488457; called by muse, mutect2, varscan2
- ACVR2A | c.255C>A p.C85* | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as COSV99604237; called by muse, mutect2, varscan2
- ADAM2 | c.1627G>T p.G543* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as COSV55870337, COSV99697056; called by muse, mutect2, varscan2
- ADAM21 | c.2051del p.L684Cfs*3 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs546931496; called by mutect2, pindel, varscan2
- ADAM8 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.114); catalogued as rs757772199, COSV101291639; called by muse, mutect2, varscan2
- ADAMTS14 | c.2950T>G p.C984G | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100941477; called by muse, mutect2, varscan2
- ADAMTSL1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs755138687, COSV52808442; called by muse, mutect2, varscan2
- ADAMTSL3 | c.629G>T p.S210I | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99717829; called by muse, mutect2, varscan2
- ADCY10 | c.2702C>T p.P901L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100896696; called by muse, mutect2, varscan2
- ADCY3 | c.1216A>G p.K406E | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV99567952; called by muse, mutect2, varscan2
- ADCY7 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775397178, COSV54266376; called by muse, mutect2, varscan2
- ADCY8 | c.2654A>G p.D885G | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV99651465; called by muse, mutect2, varscan2
- ADCY8 | c.1883C>A p.P628H | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99651467; called by muse, mutect2, varscan2
- ADD3 | c.1547T>C p.L516S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV99523282; called by muse, mutect2, varscan2
- ADGRA2 | c.1574C>G p.A525G | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs774475444, COSV100177726; called by muse, mutect2, varscan2
- ADGRB1 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs765738842, COSV100029432; called by muse, mutect2, varscan2
- ADGRE3 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 68/327 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs192735238, COSV53729478; called by muse, mutect2, varscan2
- ADGRF1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.058); catalogued as COSV99347118; called by muse, mutect2, varscan2
- ADGRG1 | c.540A>C p.K180N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as COSV101113389; called by muse, varscan2
- ADGRG6 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs753293070, COSV51588750; called by muse, mutect2, varscan2
- ADRA2A | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54527129; called by muse, mutect2, varscan2
- AFM | c.843G>A p.T281= | Splice Region (SNP) | VAF 30/125 reads (24%) | catalogued as rs752151201, COSV99888661; called by muse, mutect2, varscan2
- AGAP3 | c.375del p.X125_splice (on ENST00000622464; = p.X161_splice on NM_031946.7 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 41/226 reads (18%) | catalogued as rs758833571; called by mutect2, pindel, varscan2
- AGO4 | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1006671149, COSV100942857; called by muse, mutect2, varscan2
- AHI1 | c.3223G>A p.G1075R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as rs750115460, COSV99661636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK | c.2992A>G p.M998V | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV99946488; called by muse, mutect2, varscan2
- AHRR | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100326890; called by muse, mutect2, varscan2
- AHRR | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs373499533; called by muse, mutect2, varscan2
- AKNAD1 | c.2074T>C p.Y692H | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV100645406; called by muse, mutect2, varscan2
- AKR7A3 | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100853799; called by muse, mutect2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 11/84 reads (13%) | catalogued as rs758955164; called by mutect2, pindel, varscan2
- ALX3 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100873874; called by muse, varscan2
- AMPD2 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as COSV99857522; called by muse, mutect2, varscan2
- ANGPTL7 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776556084, COSV100815875; called by muse, mutect2, varscan2
- ANK1 | c.2111C>A p.P704H | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV99224611; called by muse, mutect2
- ANK1 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99224615; called by muse, mutect2, varscan2
- ANK3 | c.5447C>G p.T1816S | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.985); catalogued as COSV99779130; called by muse, mutect2, varscan2
- ANKFN1 | c.258dup p.H87Tfs*2 | Frame Shift Ins (INS) | VAF 24/130 reads (18%) | catalogued as rs1322720501; called by mutect2, varscan2
- ANKFY1 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.495); catalogued as rs147745463, COSV100492449; called by muse, mutect2, varscan2
- ANKRD17 | c.4873G>C p.E1625Q | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs766509752, COSV100428819; called by muse, mutect2, varscan2
- ANO6 | c.2080A>G p.N694D | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100262745; called by muse, mutect2, varscan2
- ANO8 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50175403; called by muse, mutect2, varscan2
- AOX1 | c.2951C>T p.S984F | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV101021848; called by muse, mutect2, varscan2
- AP002748.5 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.864); catalogued as rs758139447, COSV59147139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP2A1 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.996); catalogued as COSV100571066; called by mutect2, varscan2
- AP2A2 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs752237271, COSV100172535; called by muse, mutect2, varscan2
- AP3M2 | c.233_236del p.F78Sfs*23 | Frame Shift Del (DEL) | VAF 19/171 reads (11%) | catalogued as rs775391299; called by mutect2, pindel, varscan2
- AP5B1 | c.1594G>T p.G532C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); catalogued as COSV100375961; called by muse, mutect2, varscan2
- AP5Z1 | c.2003A>G p.N668S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100804053; called by muse, mutect2, varscan2
- APIP | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99551503; called by muse, mutect2
- AR | c.2111G>A p.S704N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as BM1260373, COSV101017787; called by muse, mutect2, varscan2
- ARAP3 | c.1671G>T p.Q557H | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99499509; called by muse, mutect2, varscan2
- ARC | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100751683; called by muse, mutect2
- ARFGAP1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs568574915, COSV62262205; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 64/154 reads (42%) | catalogued as rs772728725, COSV54066450; called by mutect2, varscan2
- ARFGEF1 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99141532; called by muse, mutect2, varscan2
- ARFGEF2 | c.3032C>T p.T1011M | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs138319848, COSV64212194; called by muse, mutect2, varscan2
- ARFGEF3 | c.3683A>C p.K1228T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99292880; called by muse, mutect2, varscan2
- ARHGAP17 | c.2018G>A p.R673Q (on ENST00000289968 / NM_001006634.3; = p.R595Q on NM_018054.6) | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs767131053, COSV51505900, COSV51509217; called by muse, mutect2, varscan2
- ARHGAP29 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs768915881, COSV99557872; called by muse, mutect2, varscan2
- ARHGAP39 | c.1095del p.S366Rfs*18 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | catalogued as rs751388541; called by pindel, varscan2
- ARHGEF4 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374920505; called by muse, mutect2, varscan2
- ARID1A | c.6794C>A p.P2265Q | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.875); catalogued as COSV100250894; called by muse, mutect2, varscan2
- ARL4C | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100326825; called by muse, varscan2
- ARL4C | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100326830; called by muse, varscan2
- ARL6IP4 | c.1058T>C p.M353T (on ENST00000315580 / NM_018694.3; = p.M334T on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV54902002; called by muse, mutect2, varscan2
- ARMC12 | c.866G>A p.R289Q (on ENST00000373866 / NM_001286574.2; = p.R316Q on NM_145028.5) | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.997); catalogued as rs778951542, COSV55359820; called by muse, mutect2, varscan2
- ARMC4 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs773935799, COSV59466357, COSV59472634; called by muse, mutect2, varscan2
- ARMCX2 | c.1079G>T p.R360L | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100168087, COSV57531153; called by muse, mutect2, varscan2
- ARNT2 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as COSV100308793; called by muse, mutect2, varscan2
- ARR3 | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV99333578; called by muse, mutect2, varscan2
- ARSJ | c.591dup p.G198Wfs*16 | Frame Shift Ins (INS) | VAF 33/169 reads (20%) | catalogued as rs1269648295; called by mutect2, pindel, varscan2
- ASAP1 | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs778257995, COSV100727028; called by muse, mutect2, varscan2
- ASH1L | c.2243G>A p.S748N | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); catalogued as COSV100853261; called by muse, mutect2, varscan2
- ASPH | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.615); catalogued as rs749030670, COSV101063657; called by muse, mutect2, varscan2
- ATG9A | c.2305C>G p.P769A | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); catalogued as COSV99521712; called by muse, mutect2
- ATP2B3 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781959495, COSV54848283; called by muse, mutect2, varscan2
- ATP2B4 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as COSV58178633, COSV58184803; called by muse, mutect2
- ATP5PF | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as COSV99535427; called by muse, mutect2, varscan2
- ATXN2L | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100294070, COSV100295299; called by muse, mutect2, varscan2
- AVPR2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782128197, COSV100509454; called by muse, mutect2, varscan2
- AXIN2 | c.2486C>A p.P829Q | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61060204; called by muse, mutect2
- AZU1 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99297220; called by muse, mutect2, varscan2
- B4GALNT4 | c.918del p.R307Vfs*100 | Frame Shift Del (DEL) | VAF 19/103 reads (18%) | catalogued as rs770737105, COSV57327371; called by mutect2, pindel, varscan2
- B4GALNT4 | c.2632C>T p.R878C | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV57324389; called by muse, mutect2, varscan2
- B4GALT4 | c.676T>C p.L226= | Splice Region (SNP) | VAF 24/108 reads (22%) | catalogued as COSV100785781; called by muse, mutect2, varscan2
- BAG6 | c.1169del p.P390Qfs*61 | Frame Shift Del (DEL) | VAF 20/142 reads (14%) | catalogued as rs745882580; called by mutect2, varscan2
- BAHD1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs368576045; called by muse, mutect2
- BCL11B | c.925C>T p.R309C (on ENST00000357195 / NM_001282237.2; = p.R238C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1326464268, COSV100595331; called by muse, mutect2, varscan2
- BCL9L | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs557438958, COSV100599686; called by muse, mutect2, varscan2
- BCORL1 | c.3547C>T p.R1183W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1170265378, COSV99498959; called by muse, mutect2, varscan2
- BEND3 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1316134137, COSV64681621; called by muse, mutect2, varscan2
- BEST3 | c.45del p.F15Lfs*32 | Frame Shift Del (DEL) | VAF 29/149 reads (19%) | catalogued as rs1184020574; called by mutect2, pindel, varscan2
- BMP2 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.269); catalogued as rs1294143260, COSV101122070; called by muse, mutect2, varscan2
- BMPR1A | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs905457708; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BPI | c.1108G>A p.V370M (on ENST00000262865; = p.V366M on NM_001725.3) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.084); catalogued as rs144369430; called by muse, mutect2, varscan2
- BRAF | c.1669A>G p.M557V (on ENST00000288602 / NM_001374244.1; = p.M517V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99956568; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD4 | c.3065C>T p.P1022L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs780028668, COSV54584308; called by muse, mutect2, varscan2
- BRF1 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs371981699; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 24/107 reads (22%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BRWD3 | c.2890A>G p.K964E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV100955847; called by muse, mutect2, varscan2
- BTBD11 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs776662004, COSV55023631; called by muse, mutect2, varscan2
- BTBD7 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100107974; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 68/182 reads (37%) | catalogued as rs752512017; called by mutect2, varscan2
- BTBD9 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.066); catalogued as COSV100021384; called by muse, mutect2
- C11orf65 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as rs772485445, COSV101262713, COSV67599038; called by muse, mutect2, varscan2
- C12orf40 | c.18del p.S7Pfs*6 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as COSV61129099; called by mutect2, pindel, varscan2
- C19orf57 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as rs566278344, COSV100694666; called by muse, mutect2, varscan2
- C1orf112 | c.756del p.F252Lfs*51 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs1558068270; called by mutect2, pindel
- C2CD2L | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs750634362, COSV60884096; called by muse, mutect2, varscan2
- CACNA1A | c.4621G>A p.A1541T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as rs773209223, COSV100801753; called by muse, mutect2, varscan2
- CACNA1C | c.1864G>A p.V622I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.972); catalogued as rs768270021, COSV100217287; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.4342G>A p.D1448N | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV62381909; called by muse, mutect2, varscan2
- CAMSAP3 | c.3736G>A p.G1246S | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs772932910, COSV50385051; called by muse, mutect2, varscan2
- CAMTA1 | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV100347806; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs745547658; called by mutect2, varscan2
- CAMTA2 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750858193, COSV100772516, COSV100772722; called by muse, mutect2, varscan2
- CARM1 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1568357607, COSV99449923, COSV99449985; called by muse, mutect2, varscan2
- CASKIN1 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs1226400735, COSV100399306; called by muse, mutect2, varscan2
- CASP8AP2 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs761188688, COSV52747990; called by muse, mutect2, varscan2
- CBLL1 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs556313861, COSV56030253; called by muse, mutect2, varscan2
- CBX3 | c.42del p.K14Nfs*23 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as COSV61761904; called by mutect2, pindel, varscan2
- CBX8 | c.986del p.G329Efs*27 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as rs1286129591, COSV53935816; called by mutect2, pindel, varscan2
- CBY2 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV100137535; called by muse, mutect2, varscan2
- CC2D2A | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.628); catalogued as COSV101052705; called by muse, varscan2
- CC2D2A | c.4730C>T p.A1577V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58010038; called by muse, mutect2, varscan2
- CCDC120 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.183); catalogued as rs1557080761, COSV100900596; called by muse, mutect2, varscan2
- CCDC151 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs529248956, COSV100710483; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC88B | c.3992del p.G1331Afs*278 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs767961455; called by mutect2, varscan2
- CCN4 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs753495859, COSV51531014, COSV99137013; called by muse, mutect2, varscan2
- CCR1 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV99946667; called by muse, mutect2, varscan2
- CCS | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774566620, COSV59578349; called by muse, mutect2, varscan2
- CCSER1 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.95); catalogued as rs760561993, COSV61402573, COSV61433484; called by muse, mutect2, varscan2
- CD163L1 | c.1586C>T p.T529I | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as rs765733702, COSV100549872; called by muse, mutect2, varscan2
- CD1D | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs774424909, COSV100939570; called by muse, mutect2, varscan2
- CD74 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); catalogued as COSV99153470, COSV99153584; called by muse, mutect2, varscan2
- CDADC1 | c.1387C>T p.L463F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV51913155, COSV99212540; called by muse, mutect2, varscan2
- CDC42BPA | c.3067_3069del p.P1023del (on ENST00000334218 / NM_001366019.2; = p.P1010del on NM_003607.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs778538015; called by mutect2, pindel, varscan2
- CDCP1 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs781414038, COSV99943934; called by muse, mutect2, varscan2
- CDH10 | c.322del p.T108Qfs*30 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | catalogued as rs748395403; called by mutect2, pindel, varscan2
- CDH12 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1354674210, COSV101201996; called by muse, mutect2, varscan2
- CDH23 | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs368368136, COSV56495859; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH24 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); catalogued as rs771628772, COSV57461398; called by muse, mutect2, varscan2
- CDH5 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.011); catalogued as rs745701770, COSV100439135, COSV58516604; called by muse, mutect2, varscan2
- CDH7 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs760397263, COSV59885790; called by muse, mutect2, varscan2
- CDK5R2 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100225868; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1385G>A p.R462Q (on ENST00000357886 / NM_001365728.1; = p.R448Q on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs762924338, COSV100211949, COSV59426976; called by muse, mutect2, varscan2
- CDK6 | c.542T>A p.V181D | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99720969; called by muse, mutect2
- CDX4 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100999122; called by muse, mutect2, varscan2
- CECR2 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs368613674, COSV52849609, COSV99379044; called by muse, mutect2
- CELF4 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58467413; called by muse, mutect2
- CELSR1 | c.7386C>T p.N2462= | Splice Region (SNP) | VAF 10/40 reads (25%) | catalogued as rs201235278, COSV99417546; called by muse, mutect2
- CEP128 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs769253255, COSV53674195; called by muse, mutect2, varscan2
- CEP162 | c.2912del p.K971Sfs*2 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | catalogued as rs769191604; called by mutect2, pindel, varscan2
- CEP63 | c.2055T>G p.I685M | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100132670; called by muse, mutect2
- CEP68 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs752463713, COSV53127423; called by muse, mutect2, varscan2
- CEP97 | c.1947G>A p.W649* | Nonsense Mutation (SNP) | VAF 15/155 reads (10%) | catalogued as COSV100511619; called by muse, mutect2, varscan2
- CES2 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as rs112732183, COSV100399148; called by muse, mutect2, varscan2
- CHD1 | c.629del p.K210Rfs*39 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as COSV52337505; called by mutect2, pindel, varscan2
- CHD4 | c.2398C>T p.R800C (on ENST00000357008 / NM_001363606.2; = p.R813C on NM_001273.5) | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894214; called by muse, mutect2, varscan2
- CHD9 | c.3332G>A p.R1111Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99528926; called by muse, mutect2, varscan2
- CHI3L1 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs148946875; called by muse, mutect2, varscan2
- CHID1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs750755754, COSV100059604; called by muse, mutect2, varscan2
- CHML | c.982dup p.T328Nfs*2 | Frame Shift Ins (INS) | VAF 26/140 reads (19%) | catalogued as rs1051463144; called by mutect2, pindel, varscan2
- CHRDL1 | c.397C>T p.P133S (on ENST00000372045; = p.P139S on NM_145234.4) | Missense Mutation (SNP) | VAF 118/498 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.225); catalogued as COSV99487899; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRND | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs564930869, COSV51336025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNE | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61735425, COSV99544725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST5 | c.401C>A p.P134Q | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV100291825, COSV60337465; called by muse, mutect2, varscan2
- CIAO1 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201052401, COSV99302457; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs752250702; called by mutect2, varscan2
- CKS1B | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV100460381; called by muse, mutect2, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 34/160 reads (21%) | catalogued as rs761731080; called by mutect2, varscan2
- CLMP | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs773543924, COSV101507387, COSV101507429; called by muse, mutect2, varscan2
- CLUH | c.3785G>A p.R1262Q (on ENST00000435359; = p.R1301Q on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.342); catalogued as rs1470713258, COSV101425679; called by muse, mutect2, varscan2
- CLUH | c.1324dup p.D442Gfs*99 (on ENST00000435359; = p.D480Gfs*99 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/60 reads (20%) | catalogued as rs752224729; called by mutect2, varscan2
- CLUH | c.817G>A p.A273T (on ENST00000435359; = p.A311T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as rs200340260; called by muse, mutect2, varscan2
- CMYA5 | c.8434C>A p.L2812M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV101483962, COSV71405990; called by muse, mutect2
- CMYA5 | c.11470C>T p.R3824* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as rs926232823, COSV71407144; called by muse, mutect2, varscan2
- CNTN2 | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs773485559, COSV100084820; called by muse, mutect2, varscan2
- CNTN3 | c.57T>C p.G19= | Splice Region (SNP) | VAF 11/102 reads (11%) | catalogued as rs765617781, COSV99723865; called by muse, mutect2, varscan2
- CNTN4 | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs767370642, COSV100639102; called by muse, mutect2, varscan2
- CNTNAP4 | c.2755G>A p.G919S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100270346; called by muse, mutect2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | catalogued as rs748995811; called by mutect2, varscan2
- COL12A1 | c.4660A>G p.S1554G | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.083); catalogued as COSV100485674; called by muse, mutect2, varscan2
- COL19A1 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs187031631, COSV100505808, COSV59589366, COSV59590663; called by muse, varscan2
- COL21A1 | c.2352C>T p.P784= | Splice Region (SNP) | VAF 11/48 reads (23%) | catalogued as rs200674177, COSV99780458; called by muse, mutect2, varscan2
- COL22A1 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100277322; called by muse, mutect2
- COL5A2 | c.2165C>A p.P722H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV100880114; called by muse, mutect2, varscan2
- COL6A3 | c.6282+2T>C p.X2094_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99797101; called by muse, mutect2, varscan2
- COL9A2 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.438); catalogued as rs754230024, COSV65607588; called by muse, mutect2, varscan2
- COL9A2 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV101025636; called by muse, mutect2, varscan2
- COPS2 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV100157190; called by muse, mutect2
- COQ3 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375375802, COSV54639031; called by muse, mutect2, varscan2
- CPQ | c.263T>C p.I88T | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99611263; called by muse, mutect2, varscan2
- CPXM2 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs777549768, COSV53865234; called by muse, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 31/126 reads (25%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CRLF3 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773292810, COSV100158339; called by muse, mutect2, varscan2
- CRMP1 | c.1562C>A p.S521Y | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV61478030; called by muse, mutect2, varscan2
- CRP | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.452); catalogued as COSV99660511; called by muse, mutect2, varscan2
- CSF2RA | c.109A>G p.N37D | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs775556939, COSV62625177; called by muse, mutect2, varscan2
- CSNK1G3 | c.988T>C p.L330= | Splice Region (SNP) | VAF 30/133 reads (23%) | catalogued as COSV100631416; called by muse, mutect2, varscan2
- CTAGE1 | c.2069del p.P690Hfs*30 | Frame Shift Del (DEL) | VAF 30/182 reads (16%) | catalogued as rs766584848; called by mutect2, pindel, varscan2
- CTH | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416686215, COSV100697053; called by muse, mutect2, varscan2
- CTIF | c.1376A>T p.D459V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV99837182; called by muse, mutect2, varscan2
- CTNNA1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs748407995, COSV100242448; called by muse, mutect2, varscan2
- CTNNA2 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.169); catalogued as rs764740838, COSV58163403; called by muse, mutect2, varscan2
- CTNNBL1 | c.1564C>T p.R522* | Nonsense Mutation (SNP) | VAF 14/169 reads (8%) | catalogued as rs760040999, COSV63747699; called by muse, mutect2
- CTNND2 | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs550568397, COSV100474220, COSV100479703; called by muse, mutect2
- CTSC | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1216160538, COSV99910580; called by muse, mutect2, varscan2
- CTSH | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs769006889, COSV54984511; called by muse, mutect2, varscan2
- CTSV | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as rs560756442, COSV52344066; called by muse, mutect2, varscan2
- CUL1 | c.316-1G>T p.X106_splice | Splice Site (SNP) | VAF 15/90 reads (17%) | catalogued as COSV100296534; called by muse, mutect2, varscan2
- CWF19L1 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs372238581; called by muse, mutect2, varscan2
- CWF19L2 | c.977del p.N326Ifs*19 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as COSV56519025; called by mutect2, pindel, varscan2
- CYFIP1 | c.3263G>A p.C1088Y | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV57416870; called by muse, mutect2, varscan2
- CYFIP2 | c.3731C>T p.A1244V (on ENST00000616178 / NM_001291722.2; = p.A1219V on NM_014376.4) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV59046328; called by muse, varscan2
- CYFIP2 | c.3824C>T p.A1275V (on ENST00000616178 / NM_001291722.2; = p.A1250V on NM_014376.4) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100556133; called by muse, varscan2
- CYP2S1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs202081575; called by muse, mutect2, varscan2
- CYP4F22 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99512643; called by muse, mutect2, varscan2
- DAAM1 | c.82T>C p.Y28H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.969); catalogued as COSV100658271; called by muse, mutect2, varscan2
- DACH2 | c.1573del p.T525Pfs*33 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as COSV100912973, COSV64169192; called by mutect2, pindel, varscan2
- DAXX | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1222300931, COSV99801784; called by muse, mutect2, varscan2
- DCAF10 | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as rs774687944, COSV54287521; called by muse, mutect2, varscan2
- DCAF11 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs373798935; called by muse, mutect2, varscan2
- DCDC1 | c.3607A>T p.K1203* (on ENST00000597505 / NM_001367979.1; = p.K310* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 18/140 reads (13%) | catalogued as COSV100338007; called by muse, mutect2, varscan2
- DDX10 | c.238del p.T80Hfs*2 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs1176416201; called by mutect2, pindel, varscan2
- DDX4 | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100737433; called by muse, mutect2, varscan2
- DDX49 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs752777811, COSV99447333; called by muse, mutect2, varscan2
- DDX58 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.311); catalogued as rs765663574, COSV101152650; called by muse, mutect2, varscan2
- DEAF1 | c.666C>T p.G222= | Splice Region (SNP) | VAF 20/81 reads (25%) | catalogued as rs765924884, COSV58606372; called by muse, mutect2, varscan2
- DEDD2 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs996332716, COSV100260226; called by muse, mutect2, varscan2
- DENND4C | c.966dup p.E323* | Frame Shift Ins (INS) | VAF 20/104 reads (19%) | catalogued as rs1428440687; called by mutect2, varscan2
- DENND4C | c.3409A>G p.K1137E (on ENST00000434457 / NM_001330640.2; = p.K1088E on NM_017925.7) | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs562059829, COSV100727375; called by muse, mutect2, varscan2
- DGAT1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100183977; called by muse, mutect2, varscan2
- DGKD | c.2564del p.G855Vfs*48 (on ENST00000264057 / NM_152879.3; = p.G811Vfs*48 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/103 reads (20%) | catalogued as rs35538077; called by mutect2, varscan2
- DGLUCY | c.1197G>T p.Q399H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.251); catalogued as COSV56369571; called by muse, mutect2, varscan2
- DHX34 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1430732188, COSV100169157; called by muse, mutect2, varscan2
- DHX34 | c.1144_1146del p.L382del | In Frame Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs1411109202; called by pindel, varscan2
- DIDO1 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs769538311, COSV99825309; called by muse, mutect2, varscan2
- DIP2A | c.4603G>A p.V1535M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs760258980, COSV100595532; called by muse, mutect2, varscan2
- DISP3 | c.3805dup p.H1269Pfs*115 | Frame Shift Ins (INS) | VAF 12/99 reads (12%) | catalogued as rs756156984; called by mutect2, varscan2
- DLG1 | c.150A>T p.I50= | Splice Region (SNP) | VAF 32/153 reads (21%) | catalogued as COSV100015004; called by muse, mutect2, varscan2
- DLGAP2 | c.1457A>G p.Q486R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.974); catalogued as COSV101421001; called by muse, mutect2
- DLL3 | c.1372G>A p.G458S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1352959894, COSV99218942; called by muse, mutect2
- DMTN | c.281dup p.P95Tfs*38 | Frame Shift Ins (INS) | VAF 24/202 reads (12%) | catalogued as rs772208110; called by mutect2, varscan2
- DMWD | c.1606del p.A536Qfs*123 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | catalogued as rs759256917; called by mutect2, pindel, varscan2
- DMWD | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99352916; called by muse, mutect2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH3 | c.9098T>C p.I3033T | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99765979; called by muse, mutect2, varscan2
- DNAH3 | c.8573G>A p.R2858Q | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); catalogued as rs551564037, COSV54513264; called by muse, mutect2, varscan2
- DNAH5 | c.10030del p.S3344Afs*11 | Frame Shift Del (DEL) | VAF 36/174 reads (21%) | catalogued as rs1307200375; called by mutect2, pindel, varscan2
- DNAH8 | c.12334G>A p.G4112R | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769556700, COSV59436429; called by muse, mutect2
- DNAJA2 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 100/538 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100398827; called by muse, mutect2, varscan2
- DNAJB7 | c.884del p.K295Rfs*25 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as rs768619916; called by mutect2, varscan2
- DNHD1 | c.13790G>A p.R4597H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as rs377283268; called by mutect2, varscan2
- DOCK11 | c.2263+2T>C p.X755_splice | Splice Site (SNP) | VAF 26/98 reads (27%) | catalogued as COSV99353345; called by muse, mutect2, varscan2
- DOCK3 | c.789G>T p.R263S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV99810407; called by muse, mutect2
- DOCK3 | c.2411C>T p.T804I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as COSV56549174; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK5 | c.4126C>A p.L1376I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.567); catalogued as COSV99376510; called by muse, mutect2, varscan2
- DOT1L | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs769937964, COSV67113767; called by muse, mutect2, varscan2
- DRD4 | c.605T>C p.F202S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99448563; called by muse, mutect2, varscan2
- DRD5 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as rs773943990, COSV58578778; called by muse, mutect2, varscan2
- DRG2 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56728013; called by muse, mutect2, varscan2
- DSCAM | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs747625181, COSV68634704; called by muse, mutect2, varscan2
- DSG2 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs551034751, COSV99852976; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DUOX1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757808802, COSV58487385; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | catalogued as rs746928635; called by mutect2, pindel
- DUSP8 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 75/346 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs1225509498, COSV59030179, COSV59031225; called by muse, mutect2, varscan2
- DVL2 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99138402; called by muse, mutect2, varscan2
- DVL3 | c.1995dup p.M666Hfs*45 | Frame Shift Ins (INS) | VAF 7/33 reads (21%) | catalogued as rs771967735; called by mutect2, varscan2
- DYNLT1 | c.140_142del p.V47del | In Frame Del (DEL) | VAF 18/98 reads (18%) | catalogued as rs774612118; called by pindel, varscan2
- E2F2 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs975472351, COSV100674727; called by muse, mutect2, varscan2
- ECHS1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1456511523, COSV100881890; called by muse, mutect2, varscan2
- EDC4 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as COSV54646000; called by muse, mutect2, varscan2
- EFNA4 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 39/129 reads (30%) | catalogued as rs760012398, COSV100699633; called by muse, mutect2, varscan2
- EGR1 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53521245; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF4G3 | c.1654T>C p.F552L | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99943777; called by muse, mutect2, varscan2
- EIF5A2 | c.204del p.K68Nfs*24 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as rs1366837041; called by mutect2, pindel, varscan2
- EN1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV99727066; called by muse, mutect2, varscan2
- ENO1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99318698; called by muse, mutect2, varscan2
- ENPP3 | c.1067T>C p.L356P | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100717002; called by muse, mutect2, varscan2
- EP400 | c.6478T>C p.W2160R | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100200824; called by muse, mutect2
- EPB41L4B | c.1633A>G p.K545E | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101000879; called by muse, mutect2, varscan2
- EPHA2 | c.2212C>A p.R738S | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100626055; called by muse, mutect2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 10/44 reads (23%) | catalogued as rs768793415; called by mutect2, varscan2
- ERAL1 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs754230379, COSV99650271; called by muse, mutect2, varscan2
- ERBB2 | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV54064732, COSV99507322; called by muse, mutect2, varscan2
- ERBB4 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV99619711; called by muse, mutect2, varscan2
- ESPNL | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100547694; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 36/146 reads (25%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOSC3 | c.800A>G p.Q267R | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1233655344, COSV99955963; called by muse, mutect2, varscan2
- EYA3 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs778381640, COSV65816219; called by muse, mutect2, varscan2
- FAM135A | c.3980C>T p.S1327L (on ENST00000370479 / NM_001351599.1; = p.S1114L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs975809246, COSV52060053; called by muse, mutect2
- FAM13C | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV53247128; called by muse, mutect2, varscan2
- FAM220A | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs756102302, COSV100510772; called by muse, mutect2, varscan2
- FAM98A | c.523-2A>G p.X175_splice | Splice Site (SNP) | VAF 22/90 reads (24%) | catalogued as COSV99479156; called by muse, mutect2, varscan2
- FARP1 | c.2896T>A p.S966T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100130098; called by muse, mutect2, varscan2
- FASTK | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); catalogued as COSV99879652; called by muse, mutect2, varscan2
- FAT1 | c.11737G>A p.A3913T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs773650405, COSV101499198; called by muse, mutect2, varscan2
- FAT2 | c.10946G>A p.R3649Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201335279, COSV55820955, COSV99942174; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT2 | c.5810G>A p.R1937Q | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs145637545; called by muse, mutect2, varscan2
- FAT3 | c.11902C>T p.R3968C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1171721543, COSV99963870; called by muse, mutect2
- FAT4 | c.7544T>G p.F2515C | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1402976675, COSV100627930; called by muse, mutect2, varscan2
- FBN2 | c.8G>T p.R3I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99326047; called by muse, mutect2
- FBXO43 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101413837; called by muse, mutect2
- FFAR1 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs956591250, COSV50051951; called by muse, mutect2, varscan2
- FGD3 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs749584174, COSV61599267; called by muse, mutect2, varscan2
- FGF18 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as rs745353337, COSV99208695; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 31/127 reads (24%) | catalogued as rs144178676; called by mutect2, varscan2
- FHOD1 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.262); catalogued as rs746053817, COSV99263962; called by muse, mutect2, varscan2
- FILIP1L | c.1297G>A p.A433T (on ENST00000354552 / NM_182909.3; = p.A193T on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.296); catalogued as rs368967496, COSV58775115; called by muse, mutect2, varscan2
- FITM2 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.593); catalogued as rs771219892, COSV67679095, COSV67679447; called by muse, mutect2, varscan2
- FJX1 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776372343, COSV100502633; called by muse, mutect2, varscan2
- FLG | c.3707G>A p.R1236H | Missense Mutation (SNP) | VAF 96/457 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs201976711; called by muse, mutect2, varscan2
- FLG | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 44/572 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs912328039, COSV64240961; called by muse, mutect2
- FLOT2 | c.914+2T>C p.X305_splice | Splice Site (SNP) | VAF 20/122 reads (16%) | catalogued as COSV101204758; called by muse, mutect2, varscan2
- FLOT2 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101128874; called by muse, mutect2, varscan2
- FN1 | c.4961G>A p.S1654N | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100115874; called by muse, mutect2, varscan2
- FNDC5 | c.618del p.L207Ffs*69 | Frame Shift Del (DEL) | VAF 21/107 reads (20%) | catalogued as COSV65106005; called by mutect2, pindel, varscan2
- FOXL1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV57215428; called by muse, mutect2, varscan2
- FOXO3 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100669696; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2021T>C p.L674S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV100436127; called by muse, mutect2, varscan2
- FRAS1 | c.1887del p.K630Rfs*67 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | catalogued as rs776570778; called by mutect2, pindel
- FREM2 | c.6424A>C p.S2142R | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV99747821; called by muse, mutect2, varscan2
- FSTL3 | c.660_662del p.S221del | In Frame Del (DEL) | VAF 4/46 reads (9%) | catalogued as rs769266104; called by pindel, varscan2
- FSTL4 | c.2369dup p.T791Yfs*36 | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | catalogued as rs765771244; called by mutect2, varscan2
- FSTL4 | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.346); catalogued as COSV99531946; called by muse, mutect2, varscan2
- FXR1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); catalogued as rs374389670; called by muse, mutect2, varscan2
- FYTTD1 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV99611447; called by muse, mutect2
- FZD3 | c.1533del p.H512Mfs*8 | Frame Shift Del (DEL) | VAF 15/138 reads (11%) | catalogued as rs1563404339; called by mutect2, pindel, varscan2
- FZD8 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1187243855, COSV101020200; called by muse, mutect2, varscan2
- GABRP | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs754006817, COSV54662511; called by muse, mutect2, varscan2
- GAL3ST1 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs769892145, COSV100142987; called by muse, mutect2, varscan2
- GAL3ST3 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1235317186, COSV61749295; called by muse, mutect2, varscan2
- GALNT16 | c.1185C>A p.G395= | Splice Region (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100545854; called by muse, mutect2
- GALR3 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1163835605, COSV99968011; called by muse, mutect2, varscan2
- GATA6 | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.648); catalogued as COSV99333023; called by muse, mutect2, varscan2
- GATAD2A | c.772A>G p.R258G | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99389931; called by muse, mutect2, varscan2
- GBP1 | c.1074G>T p.R358S | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.11); catalogued as COSV100976241; called by muse, mutect2, varscan2
- GCC1 | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV58463100; called by muse, mutect2, varscan2
- GDF2 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.202); catalogued as rs148790168; called by muse, mutect2, varscan2
- GDF3 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100325193; called by muse, mutect2, varscan2
- GDF6 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54626390; called by muse, mutect2
- GFPT1 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs189717232, COSV61947933; called by muse, mutect2, varscan2
- GGTLC1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1217439000, COSV99600526; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | catalogued as rs750227570; called by mutect2, varscan2
- GIT2 | c.1088C>T p.S363L (on ENST00000355312 / NM_057169.5; = p.S365L on NM_014776.5) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs763631836, COSV100188897, COSV100188918; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 61/271 reads (23%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 50/148 reads (34%) | catalogued as rs370114090; called by mutect2, varscan2
- GPR137B | c.1193T>G p.L398R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1192328419, COSV100858496; called by muse, mutect2, varscan2
- GPR173 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs781961746, COSV100212137; called by muse, mutect2, varscan2
- GPR180 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs773974365, COSV65385411; called by muse, mutect2, varscan2
- GPR37 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.37); catalogued as rs369674783; called by muse, mutect2, varscan2
- GPR78 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1239385909, COSV66762730; called by muse, mutect2, varscan2
- GPR84 | c.82del p.V28Wfs*5 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as rs759103894; called by mutect2, pindel, varscan2
- GPRC5C | c.1093C>T p.R365W (on ENST00000652232; = p.R320W on NM_018653.4) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143305891; called by muse, mutect2, varscan2
- GREB1 | c.5797G>A p.A1933T | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219740376, COSV52191764, COSV99303391; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 32/136 reads (24%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK3 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); catalogued as rs763214417, COSV66138741; called by muse, mutect2
- GRIK4 | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1467353633, COSV101483566; called by muse, mutect2, varscan2
- GRIN1 | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as COSV59300262; called by muse, mutect2, varscan2
- GRIN2A | c.4021del p.S1341Afs*56 | Frame Shift Del (DEL) | VAF 20/96 reads (21%) | catalogued as COSV58051797; called by mutect2, pindel, varscan2
- GRIP2 | c.3353G>A p.R1118H (on ENST00000619221; = p.R1021H on NM_001080423.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772124501, COSV56121048; called by muse, mutect2
- GSDME | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as rs762267830, COSV61651645; called by muse, mutect2, varscan2
- GSE1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs199764093, COSV99495869, COSV99496297; called by muse, mutect2
- GSK3B | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334056340, COSV51775360; called by muse, mutect2, varscan2
- H1-6 | c.212C>G p.A71G | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs143328743, COSV58090489; called by muse, mutect2, varscan2
- H2BC9 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.279); catalogued as COSV55099788, COSV55100388; called by muse, mutect2, varscan2
- HACD4 | c.689del p.K230Rfs*45 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | catalogued as rs768797944; called by mutect2, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs748396956; called by mutect2, varscan2
- HCRTR1 | c.44del p.P15Lfs*63 | Frame Shift Del (DEL) | VAF 29/132 reads (22%) | catalogued as rs768602707; called by mutect2, pindel, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as COSV100625709; called by mutect2, varscan2
- HDX | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV99946963; called by muse, mutect2, varscan2
- HEATR5B | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.197); catalogued as COSV99248783; called by muse, mutect2, varscan2
- HECA | c.839T>G p.L280R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.162); catalogued as COSV62771059; called by muse, mutect2, varscan2
- HELQ | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV99787529; called by muse, mutect2, varscan2
- HEPH | c.2392C>T p.R798W (on ENST00000343002; = p.R531W on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs747778042, COSV100294500, COSV57964349; called by muse, mutect2
- HERC1 | c.13372C>T p.R4458C | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs770067924, COSV101496289; called by muse, mutect2, varscan2
- HERC1 | c.7702C>T p.R2568* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV101496451; called by muse, mutect2, varscan2
- HERC2 | c.9328C>T p.H3110Y | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99872121; called by muse, mutect2, varscan2
- HERC2 | c.4287del p.E1430Sfs*16 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | catalogued as rs1567049442; called by mutect2, pindel, varscan2
- HHIP | c.1664G>A p.G555E | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99666920; called by muse, mutect2, varscan2
- HLA-B | c.626dup p.T211Dfs*10 | Frame Shift Ins (INS) | VAF 25/198 reads (13%) | catalogued as rs748204482, COSV69520417; called by mutect2, varscan2
- HLA-DOA | c.422del p.P141Lfs*2 | Frame Shift Del (DEL) | VAF 42/233 reads (18%) | catalogued as rs764712484; called by mutect2, pindel, varscan2
- HLX | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as rs1297939795, COSV65044563; called by muse, mutect2
- HMBOX1 | c.699C>T p.G233= | Splice Region (SNP) | VAF 18/117 reads (15%) | catalogued as rs372681580; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPA2B1 | c.758-2A>G p.X253_splice (on ENST00000354667 / NM_031243.3; = p.X241_splice on NM_002137.4) | Splice Site (SNP) | VAF 23/97 reads (24%) | catalogued as COSV61161114; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.712C>T p.R238C (on ENST00000354667 / NM_031243.3; = p.R226C on NM_002137.4) | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV61160567, COSV61161142; called by muse, mutect2, varscan2
- HNRNPH2 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs199773177, COSV100346983; ClinVar: uncertain significance; called by muse, mutect2
- HOGA1 | c.122del p.P41Lfs*2 | Frame Shift Del (DEL) | VAF 37/147 reads (25%) | catalogued as CM122019; called by mutect2, pindel, varscan2
- HOMEZ | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs200450330; called by muse, mutect2, varscan2
- HOXB7 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200174441, COSV99493956; called by muse, mutect2, varscan2
- HOXC8 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 83/381 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1054396326, COSV99236722; called by muse, mutect2, varscan2
- HOXD13 | c.308del p.P103Qfs*163 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs1480246716; called by mutect2, pindel, varscan2
- HOXD8 | c.329del p.P110Lfs*67 | Frame Shift Del (DEL) | VAF 23/123 reads (19%) | catalogued as rs770632206; called by mutect2, pindel
- HP | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100577475; called by muse, mutect2, varscan2
- HPS3 | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99937283; called by muse, mutect2
- HR | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs886062807, COSV57193122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HRH4 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs150959048; called by muse, mutect2, varscan2
- HS3ST1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as rs570976366, COSV50023451; called by muse, mutect2, varscan2
- HS3ST3A1 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.253); catalogued as COSV99404161; called by muse, mutect2, varscan2
- HSPG2 | c.11348C>T p.S3783F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101013385; called by muse, mutect2
- HSPG2 | c.5089C>T p.R1697W | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754726732, COSV65968827; called by mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HUWE1 | c.4611del p.F1537Lfs*4 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs35102400; called by mutect2, pindel, varscan2
- IARS2 | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV100228203; called by muse, mutect2, varscan2
- IBSP | c.784del p.E262Sfs*85 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | catalogued as COSV99883832; called by mutect2, pindel, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs747841314; called by mutect2, varscan2
- ICAM5 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as rs1320470761, COSV99703229; called by muse, mutect2, varscan2
- IDUA | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99925805; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel
- IGF1R | c.1735G>A p.V579I | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs138992740; called by muse, mutect2, varscan2
- IGF1R | c.2998A>G p.T1000A | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV51369076, COSV99150712; called by muse, mutect2, varscan2
- IGSF10 | c.2110A>G p.M704V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99177280; called by muse, mutect2, varscan2
- IGSF9B | c.3653T>C p.L1218P | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as COSV100317268; called by muse, mutect2, varscan2
- IL5RA | c.874A>G p.N292D | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV99842794; called by muse, mutect2, varscan2
- INAVA | c.1414A>G p.S472G | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1255448704, COSV100949932; called by muse, mutect2, varscan2
- INF2 | c.2977C>T p.R993C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs935688609, COSV53034132; called by muse, mutect2
- ING4 | c.500C>T p.T167I (on ENST00000396807 / NM_001127582.2; = p.T166I on NM_016162.4) | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs142380796; called by muse, varscan2
- INPPL1 | c.2813C>T p.P938L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.422); catalogued as rs144622174, COSV99035923; called by muse, mutect2, varscan2
- INTS1 | c.6046C>T p.R2016* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs201412367, COSV101247665, COSV101248357; called by muse, mutect2
- IPO7 | c.403T>G p.F135V | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV101121803; called by muse, mutect2, varscan2
- IRAK1BP1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs375099531; called by muse, mutect2, varscan2
- IRAK2 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.107); catalogued as COSV56533842; called by muse, mutect2, varscan2
- IRF5 | c.1082T>C p.I361T | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99977584; called by muse, mutect2, varscan2
- IRS4 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV100929490; called by muse, mutect2, varscan2
- IRS4 | c.240C>A p.C80* | Nonsense Mutation (SNP) | VAF 37/158 reads (23%) | catalogued as COSV100929491; called by muse, mutect2, varscan2
- ITFG1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150441201, COSV100278540; called by muse, mutect2, varscan2
- ITGA11 | c.2806C>T p.R936W | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs769771137, COSV59874740; called by muse, mutect2, varscan2
- ITGA8 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs142735096; called by muse, mutect2, varscan2
- ITGAE | c.1795del p.A599Pfs*84 | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | catalogued as COSV99560605, COSV99561817; called by pindel, varscan2
- ITGAE | c.1672G>A p.G558S | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.449); catalogued as COSV99560558, COSV99560715; called by muse, varscan2
- ITGAM | c.3069C>A p.C1023* (on ENST00000648685 / NM_001145808.2; = p.C1022* on NM_000632.4) | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV99792093; called by muse, mutect2, varscan2
- ITIH6 | c.2641A>G p.M881V | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99513065; called by muse, mutect2, varscan2
- ITPR2 | c.6989G>A p.R2330H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as rs201868488, COSV101189898; called by muse, mutect2, varscan2
- ITPRID1 | c.2416T>G p.C806G | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.15); catalogued as COSV100086025; called by muse, mutect2, varscan2
- JAG2 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs373548790; called by muse, mutect2, varscan2
- JARID2 | c.1272dup p.R425Afs*99 | Frame Shift Ins (INS) | VAF 26/105 reads (25%) | catalogued as rs747291227; called by mutect2, varscan2
- JPH1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs979194868, COSV60612901; called by muse, mutect2, varscan2
- KANK3 | c.1814G>A p.R605K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV100444913; called by muse, mutect2, varscan2
- KAT8 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1362778508, COSV54897633; called by muse, mutect2, varscan2
- KBTBD7 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 35/136 reads (26%) | catalogued as rs1448079139, COSV101068024; called by muse, mutect2, varscan2
- KCNB1 | c.2206dup p.R736Pfs*4 | Frame Shift Ins (INS) | VAF 19/98 reads (19%) | catalogued as rs759902465; called by mutect2, varscan2
- KCNC4 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs762425176, COSV100873592; called by muse, varscan2
- KCNH6 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.153); catalogued as rs745912077, COSV100120894; called by muse, mutect2, varscan2
- KCNH8 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751609797, COSV100108818; called by muse, mutect2, varscan2
- KCNJ12 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782311972, COSV100054434; called by muse, mutect2, varscan2
- KCNJ4 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV100341088, COSV57856284; called by muse, mutect2, varscan2
- KCNK1 | c.826T>A p.F276I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV100785678; called by muse, mutect2, varscan2
- KCNK6 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as COSV99649311; called by muse, mutect2, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs771351714; called by mutect2, varscan2
- KCNMA1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.988); catalogued as COSV99695386; called by muse, mutect2, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 10/97 reads (10%) | catalogued as rs754600318; called by mutect2, pindel, varscan2
- KDM4B | c.2572C>T p.R858W | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs553426005, COSV99345979; called by muse, mutect2, varscan2
- KDM5A | c.3781C>T p.R1261W | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773466573, COSV66995556; called by muse, mutect2, varscan2
- KDM5C | c.4652G>A p.C1551Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.011); catalogued as COSV64765980; called by muse, mutect2
- KIAA0100 | c.1391T>C p.V464A | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs1214674483, COSV101197263; called by muse, mutect2, varscan2
- KIAA0232 | c.1685G>T p.G562V | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100300566; called by muse, mutect2
- KIAA0930 | c.713G>A p.S238N (on ENST00000336156 / NM_001009880.2; = p.S243N on NM_015264.2) | Missense Mutation (SNP) | VAF 65/361 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1295757689, COSV52664950; called by muse, mutect2, varscan2
- KIF21A | c.2148del p.V717Lfs*12 (on ENST00000361418 / NM_001378440.1; = p.V704Lfs*12 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs1193021160; called by mutect2, varscan2
- KIF21B | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100144180; called by muse, mutect2, varscan2
- KIF25 | c.1033A>G p.R345G (on ENST00000354419 / NM_030615.2; = p.R293G on NM_005355.3) | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV100596291, COSV63027568; called by muse, varscan2
- KIF26A | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs1025697280, COSV100180975; called by muse, mutect2, varscan2
- KIF26B | c.4357G>A p.A1453T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100831932; called by muse, mutect2
- KIF4B | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as rs752730303, COSV70528482; called by muse, mutect2, varscan2
- KIRREL1 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100779625; called by muse, mutect2, varscan2
- KIRREL2 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as COSV52877886; called by muse, mutect2, varscan2
- KLC4 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765504507, COSV52435237; called by muse, mutect2, varscan2
- KLF15 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56180478; called by muse, mutect2, varscan2
- KLHL31 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.988); catalogued as rs533983995, COSV63881804; called by muse, mutect2, varscan2
- KMT5C | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs867278645, COSV55319348; called by muse, mutect2, varscan2
- KRT16 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.495); catalogued as rs777901534, CM148382, COSV100052885; called by muse, mutect2
- KRT3 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as rs370673258; called by muse, mutect2, varscan2
- KRTAP10-5 | c.90del p.C31Afs*7 | Frame Shift Del (DEL) | VAF 36/173 reads (21%) | catalogued as rs782662409; called by mutect2, pindel, varscan2
- KRTAP4-1 | c.338G>A p.R113H (on ENST00000398472; = p.R94H on NM_033060.3) | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as rs769623164, COSV66648970; called by muse, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs750491454; called by mutect2, varscan2
- L1CAM | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV100648961, COSV62828679; called by muse, mutect2, varscan2
- LAMA1 | c.4100G>A p.G1367D | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101055678; called by muse, mutect2, varscan2
- LAMA3 | c.2231T>C p.L744P | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100556081; called by muse, mutect2, varscan2
- LAMA4 | c.1668G>C p.K556N (on ENST00000230538 / NM_001105206.3; = p.K549N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV100037964; called by muse, mutect2, varscan2
- LAMB2 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs36050330; called by muse, mutect2, varscan2
- LAMB4 | c.4202G>T p.R1401M | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV52714111; called by muse, mutect2
- LAS1L | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as COSV56706542; called by muse, mutect2, varscan2
- LBHD1 | c.806C>T p.P269L (on ENST00000431002 / NM_001367940.1; = p.P243L on NM_024099.3) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs547440704, COSV100649053; called by muse, mutect2, varscan2
- LDLRAD2 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60827499, COSV60829092; called by muse, mutect2, varscan2
- LDLRAP1 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.155); catalogued as rs761580368, COSV100974707; called by muse, mutect2, varscan2
- LETM1 | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as rs762737209, COSV100245164, COSV57100334; called by muse, mutect2, varscan2
- LILRA4 | c.149A>G p.Q50R | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV99393001; called by muse, mutect2, varscan2
- LILRB1 | c.1805G>T p.S602I (on ENST00000427581; = p.S551I on NM_006669.6) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV100207105; called by muse, mutect2, varscan2
- LILRB5 | c.1762del p.L588Wfs*34 (on ENST00000449561 / NM_001081442.3; = p.L587Wfs*34 on NM_006840.5) | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | catalogued as rs775329343; called by mutect2, pindel, varscan2
- LIMCH1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs377729580; called by muse, mutect2, varscan2
- LINGO1 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs745918219, COSV100796338; called by muse, mutect2, varscan2
- LINGO2 | c.1623A>G p.I541M | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV100430391; called by muse, mutect2, varscan2
- LINS1 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs567942281, COSV100130108; ClinVar: likely benign; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | catalogued as rs780042765; called by mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LPIN3 | c.335del p.G112Vfs*69 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | catalogued as rs756955559; called by mutect2, pindel
- LRFN3 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.363); catalogued as rs770775946, COSV55817470; called by muse, varscan2
- LRFN3 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs561454282, COSV99873264; called by muse, varscan2
- LRFN4 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs751754935, COSV100540741; called by muse, mutect2, varscan2
- LRIT2 | c.769A>T p.T257S | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.371); catalogued as COSV100258643; called by muse, mutect2, varscan2
- LRP1 | c.7189A>G p.T2397A | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV99675225; called by muse, mutect2, varscan2
- LRP12 | c.7T>C p.C3R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99407454; called by muse, mutect2
- LRRC14 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.502); catalogued as rs766507601, COSV99467296; called by muse, mutect2, varscan2
- LRRC32 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as rs749558497, COSV99476794; called by muse, mutect2, varscan2
- LRRC66 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs199599093, COSV58632627; called by muse, mutect2, varscan2
- LRRC8D | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs183941207, COSV100487138; called by muse, mutect2, varscan2
- LRRIQ3 | c.1100A>G p.N367S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100598590; called by muse, mutect2, varscan2
- LRRK2 | c.4915del p.R1639Gfs*15 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | catalogued as rs756089224; called by mutect2, varscan2
- LRRN4CL | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99628059; called by muse, mutect2, varscan2
- LTK | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.269); catalogued as COSV99540712; called by muse, mutect2, varscan2
- LTV1 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as rs201919461; called by muse, mutect2, varscan2
- LUZP2 | c.683T>C p.L228S | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as COSV100419439; called by muse, mutect2, varscan2
- LVRN | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100773383; called by muse, mutect2, varscan2
- LZTS1 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1461997371, COSV99742825; called by muse, mutect2
- MACF1 | c.12601C>T p.R4201W (on ENST00000372915; = p.R2134W on NM_012090.5) | Missense Mutation (SNP) | VAF 27/141 reads (19%) | catalogued as rs374316302; called by muse, mutect2, varscan2
- MACROH2A2 | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV100951950; called by muse, mutect2, varscan2
- MAGI3 | c.2800G>A p.V934I | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.816); catalogued as COSV100288515; called by muse, mutect2, varscan2
- MAGT1 | c.565C>T p.P189S (on ENST00000618282 / NM_001367916.1; = p.P221S on NM_032121.5) | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as rs781861140, COSV100800141; called by muse, mutect2
- MAMDC2 | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV101015376; called by muse, mutect2, varscan2
- MAML2 | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as rs778085857, COSV101594076; called by muse, mutect2, varscan2
- MAOB | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100955972; called by muse, mutect2, varscan2
- MAP1B | c.4972C>A p.L1658I | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.388); catalogued as COSV99702081; called by muse, mutect2, varscan2
- MAP1S | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1395371129, COSV100140939; called by muse, mutect2, varscan2
- MAP2K7 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101209013; called by muse, varscan2
- MAP4K3 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs1006920085, COSV99810169; called by muse, mutect2, varscan2
- MAPK10 | c.-46A>G | Splice Region (SNP) | VAF 21/75 reads (28%) | catalogued as COSV100174077; called by muse, mutect2, varscan2
- MARCHF6 | c.1133T>C p.L378S | Missense Mutation (SNP) | VAF 55/337 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99929489; called by muse, mutect2, varscan2
- MARS2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV99986542; called by muse, mutect2, varscan2
- MAST3 | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1257364310, COSV53217870; called by muse, mutect2, varscan2
- MAST3 | c.2026C>T p.R676C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53221603; called by muse, mutect2, varscan2
- MAST4 | c.2828C>T p.T943I (on ENST00000403625 / NM_001164664.2; = p.T754I on NM_015183.3) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as COSV99843521; called by muse, mutect2, varscan2
- MAT1A | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100944411; called by muse, mutect2, varscan2
- MATN1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as rs368228632, COSV101056230; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 53/253 reads (21%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MCC | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 54/256 reads (21%) | catalogued as rs746372386, COSV100202304; called by muse, mutect2, varscan2
- MCC | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.075); catalogued as COSV101342720; called by muse, mutect2, varscan2
- MCEE | c.419del p.K140Rfs*6 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs776473131; called by mutect2, varscan2
- MCM3AP | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as rs148752994; called by muse, mutect2, varscan2
- MDH1B | c.414-2A>G p.X138_splice | Splice Site (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100982160; called by muse, mutect2, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MEFV | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.165); catalogued as rs768336098, COSV54821110; called by muse, mutect2, varscan2
- METTL27 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs370149363, COSV99936387; called by muse, mutect2, varscan2
- MEX3D | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66311710; called by muse, mutect2, varscan2
- MGRN1 | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as rs367720160; called by muse, mutect2, varscan2
- MIB2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs866987962, COSV61757853; called by muse, mutect2, varscan2
- MINDY4 | c.205del p.T69Qfs*49 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | catalogued as rs760174280; called by mutect2, pindel, varscan2
- MINK1 | c.3175C>T p.R1059C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771687638, COSV53420718; called by muse, mutect2, varscan2
- MIOX | c.586+2T>C p.X196_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99326753; called by muse, mutect2
- MIS18BP1 | c.1158G>T p.Q386H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV60373061; called by muse, mutect2, varscan2
- MKI67 | c.7629G>T p.R2543S | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV100896365; called by muse, mutect2, varscan2
- MMRN2 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1457155695, COSV100922533; called by muse, mutect2, varscan2
- MOSPD3 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs915732845, COSV56158319; called by muse, mutect2, varscan2
- MOXD1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); catalogued as rs146998322; called by muse, mutect2, varscan2
- MPPE1 | c.1085G>A p.C362Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as rs1353291099, COSV99303258; called by muse, mutect2, varscan2
- MR1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.92); catalogued as rs373792469; called by muse, mutect2, varscan2
- MRGPRX3 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101283509; called by muse, mutect2, varscan2
- MRPL24 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 93/441 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.113); catalogued as rs1022563019, COSV100625666; called by muse, mutect2, varscan2
- MSANTD4 | c.561del p.F187Lfs*19 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | catalogued as rs1475601536; called by mutect2, pindel, varscan2
- MSH5 | c.1186C>A p.L396I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV100994635, COSV100994797; called by muse, mutect2, varscan2
- MTHFD1L | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100944959; called by muse, mutect2, varscan2
- MTUS2 | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV101462139; called by muse, mutect2, varscan2
- MUC16 | c.31853del p.F10618Sfs*5 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | catalogued as COSV67478250; called by mutect2, pindel, varscan2
- MUC16 | c.8807del p.N2936Tfs*6 | Frame Shift Del (DEL) | VAF 16/103 reads (16%) | catalogued as COSV101198428, COSV104431809; called by mutect2, pindel, varscan2
- MYBPC2 | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs748132859, COSV100731710; called by muse, mutect2, varscan2
- MYDGF | c.421T>A p.F141I | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99501592; called by muse, mutect2, varscan2
- MYH14 | c.3581C>T p.T1194M | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs200988515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.2873del p.P958Lfs*28 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs1217492313; called by mutect2, pindel, varscan2
- MYO9A | c.3998T>C p.L1333P | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV100613011; called by muse, varscan2
- MYOF | c.3085A>G p.K1029E | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.445); catalogued as COSV100825499; called by muse, mutect2, varscan2
- MYOM3 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs745583615, COSV100292700; called by muse, mutect2, varscan2
- MYT1L | c.2687C>T p.T896I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV101219732; called by muse, mutect2, varscan2
- N4BP2L1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752396467, COSV100583028; called by muse, mutect2, varscan2
- NACC2 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs757456963, COSV53198949; called by muse, mutect2
- NBAS | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775941838, COSV55717633; called by muse, mutect2
- NBAS | c.1218C>A p.C406* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99868330; called by mutect2, varscan2
- NBEA | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs771164411, COSV59799693; called by muse, varscan2
- NCAM2 | c.842G>A p.C281Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99522281; called by muse, mutect2, varscan2
- NCAN | c.1443del p.R482Afs*5 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | catalogued as COSV53047482; called by mutect2, pindel, varscan2
- NCBP1 | c.950A>G p.N317S | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs145175516; called by muse, mutect2, varscan2
- NCF4 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199500127, COSV50628180; called by muse, mutect2, varscan2
- NCOR2 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs768882087, COSV62301261, COSV62304365; called by muse, mutect2, varscan2
- NDRG4 | c.245A>G p.Q82R (on ENST00000570248 / NM_001378344.1; = p.Q114R on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.914); catalogued as COSV99261898; called by muse, mutect2, varscan2
- NDST4 | c.1813dup p.T605Nfs*22 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | catalogued as rs1215333204; called by mutect2, pindel
- NDUFAF6 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs372973430; called by muse, mutect2, varscan2
- NDUFV2 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs886054124, COSV100571687; called by muse, mutect2
- NEFM | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV55335689; called by muse, mutect2, varscan2
- NEUROD1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54548631, COSV54549328; called by muse, mutect2, varscan2
- NEUROD2 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV100223108; called by muse, mutect2, varscan2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 56/246 reads (23%) | catalogued as rs752284115; called by mutect2, varscan2
- NEXMIF | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99280258; called by muse, mutect2, varscan2
- NFATC2 | c.2218G>A p.A740T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs758439316, COSV101043847; called by muse, mutect2, varscan2
- NFIX | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs762562838, COSV62175797; called by muse, mutect2, varscan2
- NHS | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200668785, COSV101196482; called by muse, mutect2, varscan2
- NKD2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369152047, COSV99723945; called by muse, mutect2, varscan2
- NLGN4X | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV52018138, COSV99320844; called by muse, mutect2, varscan2
- NLRP12 | c.2945T>C p.L982P | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100145054; called by muse, mutect2, varscan2
- NLRP3 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100275641, COSV60228451; called by muse, mutect2, varscan2
- NLRP9 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as rs751248353, COSV100242830; called by muse, mutect2, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 13/104 reads (13%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, pindel
- NONO | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.098); catalogued as COSV99338695; called by muse, mutect2, varscan2
- NOP14 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.266); catalogued as COSV58625163; called by muse, mutect2, varscan2
- NPAT | c.2786-3del | Splice Region (DEL) | VAF 6/54 reads (11%) | catalogued as rs35747263; called by mutect2, pindel
- NPAT | c.1618T>A p.L540I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV99585893; called by muse, mutect2, varscan2
- NPFFR2 | c.1372del p.R458Efs*10 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | catalogued as rs1405220543; called by pindel, varscan2
- NPIPA1 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100047365; called by muse, mutect2
- NR1D1 | c.119G>A p.S40N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV52841911; called by muse, mutect2, varscan2
- NR2C2 | c.773C>T p.T258I (on ENST00000393102; = p.T277I on NM_003298.5) | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100038380; called by muse, mutect2, varscan2
- NRG3 | c.1130T>A p.F377Y | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs1170526095, COSV100931045; called by muse, mutect2, varscan2
- NRXN2 | c.3388C>A p.P1130T | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99633256; called by muse, mutect2
- NUP188 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs763220109, COSV101001271; called by muse, varscan2
- NUP210L | c.2387C>T p.T796I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV99667597; called by muse, mutect2
- NUP37 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV51837771; called by muse, mutect2, varscan2
- NXNL1 | c.154C>G p.P52A | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100111953; called by muse, mutect2, varscan2
- NXNL2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs1243313885, COSV65474124; called by muse, mutect2, varscan2
- OBSCN | c.12190C>T p.R4064C | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs952042125, COSV52742967; called by muse, mutect2, varscan2
- OLFM2 | c.584G>A p.C195Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99321642; called by muse, mutect2, varscan2
- OOEP | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100949803; called by muse, mutect2, varscan2
- OPHN1 | c.1890dup p.K631Qfs*17 | Frame Shift Ins (INS) | VAF 47/252 reads (19%) | catalogued as rs1189332940; called by mutect2, pindel, varscan2
- OPLAH | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV101470744; called by muse, mutect2, varscan2
- OPN1LW | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV64064125; called by muse, mutect2, varscan2
- OPN1MW | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs1292704067, COSV100884391; called by mutect2, varscan2
- OPRK1 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99653881; called by muse, mutect2
- OR10G9 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs770016884, COSV66686503; called by muse, mutect2, varscan2
- OR10Q1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100372209; called by muse, mutect2
- OR2T4 | c.187A>C p.I63L | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100822432; called by muse, mutect2, varscan2
- OR2V2 | c.268A>G p.R90G | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.357); catalogued as COSV100080058; called by muse, mutect2, varscan2
- OR4A5 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.32); catalogued as COSV100157014; called by muse, mutect2, varscan2
- OR4C15 | c.893C>T p.A298V (on ENST00000314644; = p.A244V on NM_001001920.2) | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.149); catalogued as rs140060196, COSV100115511; called by muse, mutect2, varscan2
- OR4K5 | c.535del p.C179Vfs*20 | Frame Shift Del (DEL) | VAF 56/374 reads (15%) | catalogued as rs1566497842; called by mutect2, varscan2
- OR51Q1 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1308927708, COSV100332864; called by muse, mutect2, varscan2
- OR56A4 | c.1085T>C p.L362P | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV100417518; called by muse, mutect2, varscan2
- OR5K1 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs556272371, COSV60303891; called by muse, mutect2, varscan2
- OR5T2 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs778642834, COSV100506868; called by muse, mutect2, varscan2
- OR7G1 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV99528470; called by muse, mutect2
- OSBPL1A | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs141740509; called by muse, mutect2, varscan2
- OTUD6A | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV57973003; called by mutect2, varscan2
- OXER1 | c.231del p.S78Pfs*64 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs753912794; called by mutect2, pindel, varscan2
- OXR1 | c.1613A>C p.D538A (on ENST00000442977 / NM_001198532.1; = p.D537A on NM_018002.3) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV100367051; called by muse, mutect2, varscan2
- P2RY2 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs756233719, COSV60775725; called by muse, mutect2, varscan2
- PABPC5 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57043602; called by muse, mutect2, varscan2
- PAEP | c.204del p.E69Rfs*67 | Frame Shift Del (DEL) | VAF 14/83 reads (17%) | catalogued as COSV99478840; called by mutect2, pindel, varscan2
- PAN2 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99228196; called by muse, mutect2, varscan2
- PAPPA | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 25/118 reads (21%) | catalogued as rs143947880, COSV60279549; called by muse, mutect2, varscan2
- PAPPA2 | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs771214241, COSV62780032; called by muse, mutect2, varscan2
- PAQR8 | c.743A>C p.H248P | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100658420; called by muse, mutect2, varscan2
- PAQR9 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as COSV100503739; called by muse, varscan2
- PARD3 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as rs774764458, COSV100400645; called by muse, mutect2, varscan2
- PARP10 | c.1462T>C p.C488R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100477878; called by muse, mutect2, varscan2
- PATZ1 | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 25/128 reads (20%) | catalogued as rs751909410, COSV99315227; called by muse, mutect2, varscan2
- PAX9 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs370909756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH11X | c.4024A>G p.M1342V | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100010255; called by muse, mutect2, varscan2
- PCDHA1 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV100974422, COSV65373288; called by muse, mutect2, varscan2
- PCDHA11 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs372502721, COSV56508035; called by muse, mutect2, varscan2
- PCDHA13 | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99165447; called by muse, mutect2, varscan2
- PCDHA7 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as rs376907347; called by muse, varscan2
- PCDHA9 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.251); catalogued as rs1353719119, COSV65326183; called by muse, mutect2, varscan2
- PCDHAC1 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as rs1420415867, COSV53868229; called by muse, mutect2, varscan2
- PCDHB10 | c.2159G>T p.R720M | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99503907, COSV99503989; called by muse, mutect2, varscan2
- PCDHB11 | c.1688A>G p.Y563C | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100696954; called by muse, varscan2
- PCDHB3 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV50600078; called by muse, varscan2
- PCDHB6 | c.1006C>A p.L336M | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated, low confidence (0.69); PolyPhen probably damaging (0.999); catalogued as COSV50712088, COSV99170013; called by muse, mutect2, varscan2
- PCDHGA12 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs755015257, COSV99338971; called by muse, mutect2, varscan2
- PCDHGA7 | c.1628G>T p.S543I | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99534229; called by muse, mutect2, varscan2
- PCSK1 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100226983; called by muse, mutect2, varscan2
- PDCL | c.602G>A p.C201Y | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99414095; called by muse, mutect2, varscan2
- PDE3A | c.577del p.V193Wfs*14 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs1391469969; called by mutect2, pindel
- PDHB | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100240098; called by muse, mutect2, varscan2
- PDLIM3 | c.532G>A p.A178T (on ENST00000284770 / NM_001257963.1; = p.A345T on NM_014476.6) | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373408599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDLIM3 | c.154C>T p.R52* (on ENST00000284770 / NM_001257963.1; = p.R131* on NM_014476.6) | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | catalogued as COSV99507491; called by muse, mutect2, varscan2
- PDZD2 | c.3322del p.Q1108Sfs*17 | Frame Shift Del (DEL) | VAF 31/149 reads (21%) | catalogued as rs1212611383; called by mutect2, pindel, varscan2
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs752653446, COSV99342923; called by mutect2, varscan2
- PEPD | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370970279; called by muse, mutect2, varscan2
- PEX13 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1161796154, COSV99692744; called by muse, mutect2, varscan2
- PGRMC1 | c.454A>T p.T152S | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV99483489; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PHF3 | c.3914T>C p.M1305T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100013081; called by muse, mutect2, varscan2
- PHOX2A | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV53358125; called by muse, mutect2, varscan2
- PI4KA | c.2654T>G p.L885R | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99745273; called by muse, mutect2, varscan2
- PICALM | c.1516G>A p.G506S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100707774; called by muse, mutect2
- PIK3C2B | c.4031C>T p.T1344M | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs139230011; called by muse, mutect2, varscan2
- PIK3CB | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs143122477, COSV56686785; called by muse, mutect2, varscan2
- PITPNM3 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.999); catalogued as rs139258076; called by muse, mutect2, varscan2
- PLEKHA7 | c.2816C>T p.P939L | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs766869320, COSV100261860; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 40/210 reads (19%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHG1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372467316; called by muse, mutect2, varscan2
- PLEKHG5 | c.970A>G p.R324G (on ENST00000400915 / NM_001042663.3; = p.R287G on NM_020631.6) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV61700141; called by muse, mutect2, varscan2
- PLG | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1353611375, COSV99804428; called by muse, mutect2, varscan2
- PLIN5 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201857623, COSV67850602; called by muse, mutect2, varscan2
- PLK1 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1309116201, COSV55620826; called by muse, mutect2, varscan2
- PLPBP | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 71/599 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs766472215, COSV60239254; called by muse, mutect2, varscan2
- PLPP5 | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100395164; called by muse, mutect2, varscan2
- PLXDC1 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59550730, COSV59551444; called by muse, mutect2, varscan2
- PLXND1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1213813427, COSV100139341; called by muse, mutect2, varscan2
- PNMA2 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1563368432, COSV72908566; called by muse, mutect2, varscan2
- PNMA5 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as rs1556924334, COSV100721613; called by muse, mutect2, varscan2
- POGZ | c.1945T>C p.C649R | Missense Mutation (SNP) | VAF 69/329 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55033254, COSV99652553; called by muse, mutect2, varscan2
- POLM | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1211698188, COSV54241408; called by muse, mutect2, varscan2
- POLR1A | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.939); catalogued as rs778655256, COSV99807343; called by muse, mutect2, varscan2
- POLR1F | c.932dup p.K312Efs*6 | Frame Shift Ins (INS) | VAF 30/150 reads (20%) | catalogued as rs775851473; called by mutect2, varscan2
- POLR2A | c.2953C>T p.R985W | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548638112; called by mutect2, varscan2
- POTEE | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); catalogued as rs756695582, COSV100387425; called by muse, mutect2, varscan2
- POU3F3 | c.1463C>T p.T488M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as COSV100796846; called by muse, mutect2, varscan2
- PPFIA4 | c.3331G>A p.D1111N (on ENST00000447715; = p.D1112N on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.083); catalogued as rs1485050800, COSV99690409; called by muse, mutect2, varscan2
- PPIG | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434858664, COSV53641955; called by muse, mutect2, varscan2
956 further variants in this file (551 protein-altering or splice-affecting, 370 silent, 35 other) are not listed here.
